Gene-level copy-number profile of tumor specimen TCGA-KJ-A3U4-01A from TCGA case TCGA-KJ-A3U4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 55.8 years (20,392 days).
Specimen TCGA-KJ-A3U4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.e6ca3933-6ec1-4f3c-8243-3a86ba62186d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KJ-A3U4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a92ffdf9-eb48-4195-8d8c-abdcc3ec681c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 2: 13,680; copy number 3: 7,508; copy number 4: 33,814; copy number 5: 3,810; copy number 6: 114; copy number 7: 73; copy number 8: 280; copy number 9: 206; copy number 10: 91; copy number 11: 43; copy number 12: 15; copy number 13: 65; copy number 15: 65; copy number 17: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-KJ-A3U4-01): tumor purity 0.76, ploidy 3.58, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:34,942,287–35,673,022, 1 gene (within-gene range 0–2): NBEA.
- chr13:35,251,070–35,496,615, 3 genes: PHBP13, MAB21L1, AL390071.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 528 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:28,879,335–29,930,276, 47 genes, copy number 9: FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P, ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1.
- chr17:51,153,559–52,160,017, 14 genes, copy number 9: NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1.
- chr17:52,862,121–52,987,652, 2 genes, copy number 12: LINC02089, LINC02876.
- chr17:58,556,678–60,422,470, 74 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr17:60,677,453–61,392,838, 1 gene, copy number 15 (within-gene range 5–15): BCAS3.
- chr17:60,727,165–61,591,219, 18 genes, copy number 15: AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P, AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2.
- chr17:63,009,556–63,427,699, 1 gene, copy number 13 (within-gene range 8–13): TANC2.
- chr17:63,193,930–64,662,307, 64 genes, copy number 13 (within-gene range 5–13) (broad region; genes not listed).
- chr17:71,097,774–73,092,712, 21 genes, copy number 9 (within-gene range 5–9): CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1.
- chr18:47,390–1,408,344, 43 genes, copy number 11: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr18:6,729,716–6,915,716, 1 gene, copy number 12 (within-gene range 8–12): ARHGAP28.
- chr18:6,873,399–7,461,135, 11 genes, copy number 12: AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1.
- chr18:7,741,310–7,754,831, 1 gene, copy number 12: AP000897.2.
- chr18:9,020,029–10,626,353, 46 genes, copy number 15: RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449, PIGPP4, TXNDC2, AC006238.1, VAPA, RNA5SP450, AP005271.1, AP005209.2, AP005209.1, AP006219.1, AP006219.2, LINC01254, AP006219.3, APCDD1, NAPG, AP001099.1, LINC01887, AP001180.3, CCDC58P1.
- chr18:11,689,264–15,330,282, 134 genes, copy number 10–17 (within-gene range 8–17) (broad region; genes not listed).
- chr19:27,983,032–30,228,715, 50 genes, copy number 9: AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
